Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A5C7, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A5C7-01A (Primary Tumor).

TISSUE DESCRIPTION:

' A1 B1 C1 D1 D2 D3 D4 D5 D6 D7 D8 E1 F1
Left upper lobe lung (185.0 grams), station 6 lymph nodes, station 7
lymph nodes, station 9L lymph nodes, station 10L lymph nodes,
station 11L lymph nodes.

DIAGNOSIS:

Lung, left upper lobe, lobectomy: Invasive grade 2 (of 4)
adenocarcinoma, forming a well-circumscribed 4.0 x 3.0 x 2.6 cm
central mass, puckering the pleura but without visceral pleural
invasion. The bronchial margin is negative for tumor (by 4.0 cm).

Lymph nodes, intrapulmonary/hilar, excision:

- No tumor is identified in multiple (11) intrapulmonary
peribronchial lymph nodes.

- No tumor is identified in a single (1) left hilar
(station 10L) lymph node.

- No tumor is identified in multiple (2) left interlobar
(station 11L) lymph nodes.

Lymph nodes, mediastinal, excision:

- No tumor is identified in multiple (2) para-aortic
(station 6) lymph nodes.

- No tumor is identified in multiple (2) subcarinal
(station 7) lymph nodes.

- No tumor is identified in a single (1) left pulmonary
ligament (station 9L) lymph node.

ICD-b-3

Adenocarcinoma NOS 8140/3

Site: ④ Lung, upper lobe C34.1

grd 1/16/13

Source: NCI Genomic Data Commons file 6595d0c6-1924-46af-8a94-1d08c15d7094 (TCGA-MP-A5C7.656F0756-05CC-437B-98D4-C2AED4B77DAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).